Somatic mutation profile of tumor specimen MMRF_2026_1_BM_CD138pos (aliquot MMRF_2026_1_BM_CD138pos_T1_KHS5U_L08651) from MMRF case MMRF_2026, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.1 years (22,322 days).
Specimen MMRF_2026_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d095f46-d894-4b51-a32c-2741ac2f6f02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2026_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2026_1_PB_Whole_C2_KHS5U_L08652; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4618d4e6-cad4-4c86-a86d-8ec16fa9b7bd

The open-access MAF lists 93 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 21, Silent 10, Intron 9, 5'UTR 8, Splice Site 3, 5'Flank 2, RNA 2, Splice Region 1, Frame Shift Del 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAMTS9 | c.4985C>T p.T1662M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs143180629; called by muse, mutect2, varscan2
- AFF2 | c.2776C>T p.R926C | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1312069228, COSV54000517, COSV54002779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFF2 | c.3889G>A p.V1297I | Missense Mutation (SNP) | VAF 80/165 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.239); catalogued as rs782158550, COSV53977919; called by muse, mutect2, varscan2
- ALOX15 | c.1316G>A p.S439N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.139); catalogued as COSV53400239; called by muse, mutect2, varscan2
- CACNA2D3 | c.2799G>C p.W933C | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55535505; called by muse, mutect2, varscan2
- FTMT | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs572583166; called by muse, mutect2, varscan2
- GGN | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.782); catalogued as rs569509632; called by muse, mutect2, varscan2
- IFNL3 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69830204; called by muse, mutect2, varscan2
- IGHJ4 | c.10T>G p.Y4D | Missense Mutation (SNP) | VAF 34/43 reads (79%) | PolyPhen benign (0.103); catalogued as rs367800003; called by muse, varscan2
- PPP1R3A | c.1708A>T p.T570S | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV52891002; called by muse, mutect2, varscan2
- PRDM1 | c.1877C>T p.T626M | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64844620; called by muse, mutect2, varscan2
- SHISA7 | c.1504G>T p.A502S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV66244827; called by muse, mutect2, varscan2
- ZDHHC13 | c.1184G>C p.W395S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV101240065; called by muse, mutect2, varscan2
- ZNF229 | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs370593038; called by muse, mutect2, varscan2
- ABCA1 | c.4279A>C p.T1427P | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- BNC2 | c.256A>C p.T86P | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- C10orf82 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CACNA1H | c.3848T>C p.F1283S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CAPS2 | c.482A>C p.N161T | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL6A5 | c.1834G>A p.V612I | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- COL7A1 | c.7460G>A p.G2487D | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- FBN1 | c.3589+2T>C p.X1197_splice | Splice Site (SNP) | VAF 49/84 reads (58%) | called by muse, mutect2, varscan2
- GOLPH3 | c.354_357+24del p.X118_splice | Splice Site (DEL) | VAF 28/74 reads (38%) | called by mutect2, pindel*
- HIVEP1 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IRAK2 | c.690C>G p.H230Q | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ITPKB | c.487G>C p.A163P | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, varscan2
- LGR4 | c.1912C>A p.L638I | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYH11 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- MYO16 | c.2889T>A p.F963L | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- MYPN | c.3446C>T p.T1149I | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NLRP3 | c.2675C>T p.S892F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2
- OTOG | c.2425G>C p.D809H | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.435); called by muse, varscan2
- PCDH8 | c.1106C>G p.P369R | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- PIK3R6 | c.189+1G>T p.X63_splice | Splice Site (SNP) | VAF 63/142 reads (44%) | called by muse, mutect2, varscan2
- RTRAF | c.462+3C>T | Splice Region (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- TBX4 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- VPS13C | c.5235del p.D1746Tfs*10 (on ENST00000644861 / NM_020821.3; = p.D1703Tfs*10 on NM_017684.5) | Frame Shift Del (DEL) | VAF 45/123 reads (37%) | called by mutect2, pindel, varscan2
- WWTR1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF415 | c.767A>T p.K256I | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CALR | c.60C>A p.A20= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as rs1448200199; called by muse, mutect2, varscan2
- COL6A2 | c.390C>T p.R130= | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as rs544610322, COSV56017387; ClinVar: likely benign; called by muse, mutect2, varscan2
- FCGBP | c.7950C>T p.P2650= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as rs764102330; called by muse, mutect2
- FLNC | c.7341C>T p.P2447= | Silent (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- FNDC1 | c.2031G>T p.P677= | Silent (SNP) | VAF 38/79 reads (48%) | called by muse, mutect2, varscan2
- IGHJ6 | c.61G>C p.*21= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs368258322; called by muse, varscan2
- ITPKB | c.576T>A p.V192= | Silent (SNP) | VAF 43/97 reads (44%) | called by muse, varscan2
- MELTF | c.600C>T p.D200= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs781555290; called by muse, mutect2, varscan2
- MPDZ | c.1206T>G p.P402= | Silent (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- TLX1 | c.790C>A p.R264= | Silent (SNP) | VAF 34/35 reads (97%) | called by muse, mutect2, varscan2
- AKT3 | c.*1779A>G | 3'UTR (SNP) | VAF 24/39 reads (62%) | called by muse, mutect2, varscan2
- ANKS6 | c.*4190A>G | 3'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- AR | c.*6145dup | 3'UTR (INS) | VAF 16/18 reads (89%) | catalogued as rs969114410; called by mutect2, varscan2
- C9orf85 | c.-56T>C | 5'UTR (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- CDH15 | c.*291C>A | 3'UTR (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- CHMP4C | c.*165A>G | 3'UTR (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- DCLRE1C | c.973-313G>A | Intron (SNP) | VAF 12/30 reads (40%) | catalogued as rs1030585223; called by muse, varscan2
- DHX36 | c.2567+46A>C | Intron (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- FAM205BP | n.3939G>A | RNA (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- FOXI1 | c.-12C>T | 5'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- FSD1L | c.*5074G>A | 3'UTR (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- GALNT13 | c.*3205T>G | 3'UTR (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- GRM2 | c.1288+757G>A | Intron (SNP) | VAF 50/157 reads (32%) | called by muse, mutect2, varscan2
- GRSF1 | c.357+180C>G | Intron (SNP) | VAF 72/135 reads (53%) | catalogued as rs1307764814; called by muse, mutect2, varscan2
- IGHV1-69D | c.-30A>T | 5'UTR (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- IMP3 | c.-17C>G | 5'UTR (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- IPMK | c.*1990T>A | 3'UTR (SNP) | VAF 41/83 reads (49%) | catalogued as rs1023471488; called by muse, mutect2, varscan2
- LAMP2 | c.1093+4461G>T | Intron (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- LINC02054 | n.44G>T | RNA (SNP) | VAF 31/91 reads (34%) | catalogued as rs1245452804; called by muse, mutect2, varscan2
- LTV1 | c.*57G>A | 3'UTR (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- MEST | c.*938T>C | 3'UTR (SNP) | VAF 97/285 reads (34%) | called by muse, mutect2, varscan2
- MS4A6A | c.652-184G>T | Intron (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- MYBL1 | c.-72G>A | 5'UTR (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- MYZAP | c.*280G>T | 3'UTR (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- NNT | c.*611A>C | 3'UTR (SNP) | VAF 23/56 reads (41%) | catalogued as rs1412452390; called by muse, mutect2, varscan2
- NR1D2 | c.*335T>G | 3'UTR (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- PCBP1 | c.-29A>G | 5'UTR (SNP) | VAF 26/62 reads (42%) | catalogued as rs776976460; called by muse, varscan2
- PPM1J | c.326+13del | Intron (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- PRSS16 | c.*246T>C | 3'UTR (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- ROBO1 | c.88+81867C>A | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- SCRN1 | c.*1445G>A | 3'UTR (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- SEC31A | c.782+67G>T | Intron (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- SEMA3D | c.-1C>T | 5'UTR (SNP) | VAF 45/154 reads (29%) | called by muse, mutect2, varscan2
- SIMC1 | c.-214G>A | 5'UTR (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- SLC24A1 | c.*85T>G | 3'UTR (SNP) | VAF 50/100 reads (50%) | called by muse, mutect2, varscan2
- SLC24A1 | c.*86A>G | 3'UTR (SNP) | VAF 46/95 reads (48%) | called by muse, varscan2
- SLC38A4 | c.*409G>T | 3'UTR (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- SORCS3 | c.*497T>C | 3'UTR (SNP) | VAF 17/22 reads (77%) | called by muse, mutect2, varscan2
- SPECC1 | chr17:20318926 T>A | 3'Flank (SNP) | VAF 74/168 reads (44%) | called by muse, mutect2, varscan2
- SPOCK3 | c.*554G>T | 3'UTR (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- STK40 | c.*1298C>T | 3'UTR (SNP) | VAF 33/62 reads (53%) | called by muse, mutect2, varscan2
- SYBU | chr8:109646688 G>A | 5'Flank (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- USP48 | chr1:21783372 T>A | 5'Flank (SNP) | VAF 114/203 reads (56%) | called by muse, mutect2, varscan2
